Somatic mutation profile of tumor specimen 0DPJT6 from CCDI case PBCDSK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 7.1 years (2,592 days).
Specimen 0DPJT6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a38f3890-412e-48df-a25f-8625ba301dfd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPJSA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/649226e6-9237-40c6-8afa-699c00984525

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, In Frame Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 194/346 reads (56%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 197/455 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs1567009054, COSV61069333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OAF | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376270711; called by muse, mutect2, varscan2
- SNRNP48 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 194/389 reads (50%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as rs960995526; called by muse, mutect2, varscan2
- USP53 | c.1372T>G p.L458V | Missense Mutation (SNP) | VAF 162/414 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99918059; called by muse, mutect2, varscan2
- IFT52 | c.413+2T>C p.X138_splice | Splice Site (SNP) | VAF 213/475 reads (45%) | called by muse, mutect2, varscan2
- IRX2 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.056); called by muse, mutect2
- OR4K14 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PIK3R1 | c.1353_1358del p.E451_N453delinsD (on ENST00000521381 / NM_181523.3; = p.E181_N183delinsD on NM_181504.4) | In Frame Del (DEL) | VAF 86/251 reads (34%) | called by mutect2, pindel, varscan2
- TRAM2 | c.856T>G p.F286V | Missense Mutation (SNP) | VAF 176/427 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VWF | c.6107G>C p.G2036A | Missense Mutation (SNP) | VAF 149/370 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ACAN | c.1677C>T p.G559= | Silent (SNP) | VAF 35/412 reads (8%) | catalogued as COSV61361630; called by muse, mutect2
- ALOX12B | c.1155A>G p.V385= | Silent (SNP) | VAF 140/297 reads (47%) | called by muse, mutect2, varscan2
- EFCAB6 | chr22:43528753 ins T | 3'Flank (INS) | VAF 56/134 reads (42%) | catalogued as rs377172517; called by mutect2, varscan2
